Somatic mutation profile of tumor specimen TARGET-20-PARTYV-09A (aliquot TARGET-20-PARTYV-09A-01D) from TARGET case TARGET-20-PARTYV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,636 days).
Specimen TARGET-20-PARTYV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f49a5b8-6b9a-4b54-a9cf-469b267fd89e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARTYV-14A (Bone Marrow Normal), aliquot TARGET-20-PARTYV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90fc32f6-53af-4a27-a782-ea6d343c7099

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 3'UTR 3, 5'UTR 1, In Frame Ins 1, Splice Region 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.186_190del p.D63Qfs*43 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | catalogued as rs1060502121; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AHNAK2 | c.3370G>A p.V1124M | Missense Mutation (SNP) | VAF 171/375 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.127); catalogued as rs1256580161; called by muse, varscan2
- AHNAK2 | c.3367G>A p.E1123K | Missense Mutation (SNP) | VAF 170/376 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1253216001; called by muse, varscan2
- ATN1 | c.772A>C p.T258P | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs782046159; called by muse, mutect2, varscan2
- EVC | c.184A>C p.T62P | Missense Mutation (SNP) | VAF 116/222 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.282); catalogued as rs143898721; called by muse, varscan2
- FAT1 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 174/380 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs374843828; called by muse, mutect2, varscan2
- INTS1 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762191417; called by muse, mutect2, varscan2
- SERPINA10 | c.1075A>G p.R359G | Missense Mutation (SNP) | VAF 114/218 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs139982545; called by muse, mutect2, varscan2
- TIAM1 | c.2249A>G p.H750R | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.103); catalogued as rs762439715; called by muse, mutect2, varscan2
- WT1 | c.1338_1339insTTC p.R446_K447insF | In Frame Ins (INS) | VAF 89/172 reads (52%) | catalogued as COSV60068878, COSV60084004, COSV99070046, COSV99070049; called by mutect2, pindel, varscan2
- CEBPA | c.921_939delinsAGCA p.N307_K313delinsKA | In Frame Del (DEL) | VAF 50/110 reads (45%) | called by pindel, varscan2*
- PTPRF | c.3277A>G p.I1093V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WT1 | c.1213+2_1213+3insTCT | Splice Region (INS) | VAF 74/168 reads (44%) | called by mutect2, pindel, varscan2
- HERC1 | c.4002A>G p.A1334= | Silent (SNP) | VAF 97/188 reads (52%) | catalogued as rs766264556; called by muse, mutect2, varscan2
- KDR | c.1404C>T p.N468= | Silent (SNP) | VAF 78/168 reads (46%) | catalogued as rs141384787; called by muse, mutect2, varscan2
- USP34 | c.7524A>G p.K2508= | Silent (SNP) | VAF 127/270 reads (47%) | catalogued as rs762631367; called by muse, mutect2, varscan2
- ARFGEF3 | c.*6053_*6055del | 3'UTR (DEL) | VAF 148/334 reads (44%) | catalogued as rs577176354; called by pindel, varscan2
- GAREM1 | c.*370_*371insC | 3'UTR (INS) | VAF 28/187 reads (15%) | catalogued as rs1491532842; called by pindel, varscan2
- SIN3A | c.*623C>T | 3'UTR (SNP) | VAF 115/265 reads (43%) | catalogued as rs1240132262; called by muse, mutect2, varscan2
- TPR | c.-82G>T | 5'UTR (SNP) | VAF 59/118 reads (50%) | catalogued as rs746897607; called by muse, mutect2, varscan2
